Gene-level copy-number profile of tumor specimen TCGA-WT-AB41-01A from TCGA case TCGA-WT-AB41, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB.
Specimen TCGA-WT-AB41-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.64a77049-5d0c-4cc6-ba17-014e39eb7711.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WT-AB41-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f568ee5c-8bc3-4448-8b01-35d0bf77da62

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 17,131; copy number 2: 36,498; copy number 3: 2,627; copy number 4: 3,262; copy number 5: 94; copy number 6: 25; copy number 8: 6; copy number 10: 3; copy number 11: 86; copy number 14: 5; copy number 18: 80.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WT-AB41-01A-11D-A41E-01): tumor purity 0.51, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 299 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:108,815,898–108,963,484, 1 gene, copy number 5 (within-gene range 4–5): AKNAD1.
- chr1:108,875,350–109,632,053, 34 genes, copy number 5: GPSM2, CLCC1, WDR47, BX679664.2, BX679664.3, BX679664.1, RANP5, TAF13, AL356488.3, TMEM167B, SCARNA2, AL356488.2, AL356488.1, C1orf194, ELAPOR1, SARS1, CELSR2, PSRC1, MYBPHL, SORT1, PSMA5, SYPL2, ATXN7L2, CYB561D1, AMIGO1, GPR61, AL355310.3, GNAI3, RNU6V, AL355310.1, MIR197, GNAT2, AMPD2, AL355310.2.
- chr1:110,848,077–111,323,981, 19 genes, copy number 5 (within-gene range 2–5): NRBF2P3, OR11I1P, CD53, AL360270.2, AL360270.1, LRIF1, AL360270.3, CCNT2P1, RNA5SP54, DRAM2, CEPT1, AL355816.1, AL355816.2, DENND2D, CHI3L2, CHIAP1, CHIAP2, CHIA, AL356387.1.
- chr3:128,879,596–129,002,690, 3 genes, copy number 5 (within-gene range 1–5): ACAD9, CFAP92, AC112484.4.
- chr5:163,416,525–163,709,514, 8 genes, copy number 6: AC008723.1, CCNG1, NUDCD2, HMMR, HMMR-AS1, MAT2B, AC010291.1, AC116917.1.
- chr5:165,905,126–166,155,439, 3 genes, copy number 10: AC008489.1, RPL7P20, AC114321.1.
- chr5:172,755,457–173,329,503, 25 genes, copy number 5: AC022217.2, AC022217.1, AC022217.3, DUSP1, Y_RNA, AC022217.4, AC110011.1, ERGIC1, AC008429.1, AC008429.3, RPL26L1, AC008429.2, ATP6V0E1, AC008429.4, SNORA74B, Y_RNA, CREBRF, CDC42P5, AC008378.1, BNIP1, RPL7AP33, NKX2-5, Y_RNA, RNA5SP200, STC2.
- chr8:33,969,567–43,674,591, 199 genes, copy number 5–18 (broad region; genes not listed).
- chr15:27,621,534–28,322,179, 7 genes, copy number 5 (within-gene range 1–5): AC021979.1, AC021979.3, AC021979.2, OCA2, AC090696.1, RPL5P32, HERC2.

Autosomal genes at a single copy (total copy number 1): 14,768. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
